Surgical pathology report (de-identified scan), TCGA case TCGA-BK-A139, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-BK-A139-01A (Primary Tumor).

[page 1 of 3]
UID:SF8C376B-31F8-4566-8EBF-21E7F4E6499D

106-0-3

Adenocarcinoma, Endometrioid, NOS

838013

hw
11/16/10

Site: Endometrium C54.1

SPECIMEN

- A. Uterus, cervix, bilateral tubes and ovaries
- B. Cervical margin
- C. Right pelvic peritoneal biopsy
- D. Right pelvic lymph nodes
- E. Periaortic lymph nodes
- F. Left pelvic peritoneal biopsy
- G. Left pelvic lymph nodes
- H. Omentum

CLINICAL NOTES

PRE-OP DIAGNOSIS: Uterine carcinoma.

GROSS DESCRIPTION

A. Part A received fresh, labeled "uterus, cervix, bilateral tubes and ovaries", is a 100 gram, 5.5 x 5.5 x 4.0 cm. symmetrical uterine corpus with attached 1.4 cm. of lower uterine segment and bilateral adnexa. The cervical tissue is not present. The 5.0 x 3.9 cm. uterine cavity contains abundant soft tan white-red tumor, both anteriorly and posteriorly. A scant amount of uninvolved endometrium is present posteriorly, which appears smooth tan pink and averages 0.15 cm. in thickness. Anteriorly, the tumor spans an area of 5.4 x 4.2 cm. and posteriorly, the tumor spans an area of 4.2 x 3.8 cm. On sectioning, the tumor has a maximal thickness of 1.8 cm., grossly involving up to 50% of the myometrium. The myometrium is tan pink and measures up to 1.8 cm. in thickness, with a single, posterior 1.4 cm. well circumscribed rubbery whorled tan white intramural leiomyoma. The right ovary is cystic and focally disrupted, measuring 6.0 x 4.0 x 0.3 cm. The cyst is vacant with a smooth tan white inner lining. The left ovary is cerebriiform, pale tan gold and measures 1.6 x 1.1 x 0.9 cm. On sectioning, the stroma is pale tan with identifiable corpora albicantia. Bilaterally, the fimbriated tan pink right and left fallopian tube segments average

GROSS DESCRIPTION

5.5 cm. in length and 0.3 cm. in diameter with pinpoint stellate lumen on sectioning. Representative sections are submitted in thirteen blocks as labeled. RS-13.

BLOCK SUMMARY: 1 - Anterior and posterior lower uterine segments (distal anterior inked blue; distal posterior inked black); 2-5 - representative anterior endomyometrium including tumor full thickness sequentially from fundus to LUS; 6-9 - representative posterior endomyometrium sequentially from fundus to LUS; 10-12 - right tube and ovary; 13 - left tube and ovary.

B. Part B received fresh, labeled "cervical margin" is an amputated 2.4 cm. cervix. The diffusely torn 2.4 x 2.2

cm.

white pink ectocervix surrounds a 0.4 x 0.2 cm. ovoid os. The

[page 2 of 3]
paracervical margin is inked blue and the cervical mucosa is glistening and mildly trabecular tan pink-red. Representative sections are submitted in two blocks as labeled. RS-2.

BLOCK SUMMARY: 1 - Anterior cervix; 2 - posterior cervix.

C. Part C received fresh, labeled "right pelvic peritoneal biopsy" is a focally cauterized, 2.1 x 1.1 x 0.3 cm. portion of soft tan gold-pink fatty tissue. The specimen is sectioned and entirely submitted in one block. AS-1.

D. Part D received fresh, labeled "right pelvic lymph node", is a 4.8 x 4.5 x 2.7 cm. aggregate of soft, lobulated golden yellow adipose tissue. Several soft to slightly rubbery tan pink-gold tissues in keeping with lymph nodes measuring up to 1.8 cm. in greatest dimension are recovered. The lymphoid tissues are entirely submitted in six blocks. RS-6.

BLOCK SUMMARY: 1,2 - Four whole lymph nodes per cassette; 3-6 - one bisected lymph node per cassette.

E. Part E received fresh, labeled "periaortic lymph node"

GROSS DESCRIPTION

is a 4.8 x 4.4 x 1.8 cm. aggregate of soft, lobulated golden yellow adipose tissue. Several soft tan pink-gold tissues, in keeping with lymph nodes measuring up to 3 cm. in greatest dimension are recovered. The lymphoid tissues are entirely submitted in four blocks as labeled. RS-4.

BLOCK SUMMARY: 1,2 - Four whole lymph nodes per cassette; 3,4 - bisected largest lymph nodes (one-half per cassette).

F. Part F received fresh, labeled "left pelvic peritoneal biopsy" is a focally cauterized, 3.4 x 2.4 x 0.3 cm. soft tan gold-pink fatty portion of tissue which is sectioned and entirely submitted in one block. AS-1.

G. Part G received fresh, labeled "left pelvic lymph node" is a 5.5 x 4.5 x 2.0 cm. aggregate of soft, lobulated golden yellow adipose tissue. Several soft tan gold tissues in keeping with lymph nodes measuring up to 1.9 cm. in greatest dimension are recovered. The lymphoid tissues are entirely submitted in five blocks as labeled. RS-5.

BLOCK SUMMARY: 1,2 - Four whole lymph nodes per cassette; 3-5 - one bisected lymph node per cassette.

H. Part H received fresh, labeled "omentum" is a 15.0 x 13.0 x 2.5 cm. portion of soft, lobulated tan gold adipose tissue in keeping with omentum. No discrete mass lesion or abnormality is identified on sectioning. Random representative sections are submitted in eight blocks. RS-8.

[page 3 of 3]
MICROSCOPIC DESCRIPTION

Histologic type: Endometroid adenocarcinoma with a minor component of serous adenocarcinoma.

Histologic grade: The endometroid adenocarcinoma is grade 3.

Myometrial invasion:

0.9 cm. depth of invasion

1.7 cm. depth of myometrial thickness

>50% of myometrial wall

Cervix: Negative for tumor

Primary tumor (pT) TNM (FIGO): pT1b

Margins of resection: Negative for tumor.

Vascular invasion: Present.

Regional lymph nodes (pN): pN0.

Distant metastasis (pM): pM0

5x1, 3x4, 4x3

DIAGNOSIS

A. Uterus, cervix, fallopian tubes and ovaries, hysterectomy with bilateral salpingo-oophorectomy - Grade 3 endometroid adenocarcinoma

with a minor component of serous carcinoma (see tumor characteristics in the hysterectomy template).

B. Uterus, cervix, excision - Negative for tumor.

C. Right pelvic peritoneal biopsy - Acute and chronic inflammation reactive changes, negative for tumor.

D. Lymph nodes, right pelvic, excision - Fourteen lymph nodes negative for metastatic carcinoma (0/14).

E. Lymph nodes, periaortic, excision - Nine lymph nodes negative for metastatic carcinoma (0/9 endometrium).

F. Soft tissue, left pelvic peritoneum, biopsy - Acute and chronic inflammation with reactive changes.

G. Lymph nodes, left pelvic, excision - Ten lymph nodes negative for metastatic carcinoma (0/10).

DIAGNOSIS

H. Omentum, partial excision - Acute and chronic inflammation with reactive changes; negative for tumor.

D. (Electronic Signature)

--- End Of Report ---

Case is (curable)	☒	☒
Reviewer Initials	☒	☒

Source: NCI Genomic Data Commons file dc836296-99c2-4ed6-a7eb-8b42b95a2528 (TCGA-BK-A139.5F8C376B-31F8-4566-8EBF-21E7F4E6499D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).